Gene-level copy-number profile of tumor specimen ALCH-B466-TTP1-A from ALCHEMIST case ALCH-B466, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 60.3 years (22,013 days).
Specimen ALCH-B466-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 3fc19c74-0f6a-4816-92a9-f413e32b3b0c.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B466-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,225 have no estimate.
https://portal.gdc.cancer.gov/files/11257074-3ab7-4994-aaee-53344a6e83d0

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 29; copy number 1: 564; copy number 2: 57,610; copy number 3: 186; copy number 4: 6; copy number 5: 3.

Homozygous deletions (total copy number 0; autosomes only): 29 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:130,111,669–130,201,336, 1 gene (within-gene range 0–2): LINC02021.
- chr7:51,382,284–51,384,660, 1 gene: CICP17.
- chr7:100,868,036–100,868,107, 1 gene (within-gene range 0–2): MIR6875.
- chr7:140,435,316–140,435,787, 1 gene: AC069335.1.
- chr11:64,340,204–64,357,534, 2 genes: CCDC88B, MIR7155.
- chr15:25,184,306–25,208,163, 14 genes (within-gene range 0–2): SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21.
- chr16:67,987,394–68,000,586, 1 gene (within-gene range 0–2): DPEP2.
- chr17:3,923,870–3,964,464, 1 gene: ATP2A3.
- chr20:50,620,763–50,621,077, 1 gene (within-gene range 0–2): RPL36P2.
- chr20:63,939,829–63,956,416, 3 genes (within-gene range 0–2): UCKL1, MIR1914, MIR647.
- chr22:41,525,799–41,577,741, 3 genes (within-gene range 0–2): POLR3H, AL023553.1, CSDC2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:6,754,109–6,799,365, 1 gene, copy number 5 (within-gene range 2–5): RSPH10B2.
- chr14:104,677,694–104,677,749, 1 gene, copy number 5: MIR4710.
- chr16:28,364,700–28,365,333, 1 gene, copy number 5: AC138894.3.

Autosomal genes at a single copy (total copy number 1): 454. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
